Somatic mutation profile of tumor specimen HCM-BROD-0472-C34-06B (aliquot HCM-BROD-0472-C34-06B-21D-A80U-36) from HCMI case HCM-BROD-0472-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 65.9 years (24,082 days).
Specimen HCM-BROD-0472-C34-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de7ce12f-d5b4-47f9-926c-394f99c4ff14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0472-C34-10A (Blood Derived Normal), aliquot HCM-BROD-0472-C34-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/693565cc-cbff-4c7e-848e-41acfd424d4a

The open-access MAF lists 503 somatic variants for this specimen: 359 protein-altering or splice-affecting, 123 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 311, Silent 123, Nonsense Mutation 23, Frame Shift Del 16, Intron 11, Splice Site 4, 5'Flank 4, 5'UTR 4, In Frame Del 3, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 110/142 reads (77%) | catalogued as rs121913304, CM942039, COSV57296489; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 134/170 reads (79%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs780077643, COSV56853758; called by muse, mutect2, varscan2
- AC136428.1 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 135/267 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.514); catalogued as rs1261897585; called by muse, mutect2, varscan2
- ACTN3 | c.2043G>C p.Q681H | Missense Mutation (SNP) | VAF 106/402 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV59747326; called by muse, mutect2, varscan2
- ADCY8 | c.13G>T p.D5Y | Missense Mutation (SNP) | VAF 88/298 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.301); catalogued as rs566810608; called by muse, mutect2, varscan2
- ALPK2 | c.3805C>T p.P1269S | Missense Mutation (SNP) | VAF 232/290 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs573563411, COSV100863938; called by muse, mutect2, varscan2
- ANK2 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 225/320 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99053417; called by muse, mutect2, varscan2
- APOBEC4 | c.545C>A p.P182Q | Missense Mutation (SNP) | VAF 295/490 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58017650; called by muse, mutect2, varscan2
- ATXN2 | c.2837C>T p.P946L (on ENST00000550104; = p.P786L on NM_002973.4) | Missense Mutation (SNP) | VAF 183/234 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66483733; called by muse, mutect2, varscan2
- BOC | c.1100A>T p.Q367L | Missense Mutation (SNP) | VAF 232/633 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as rs779844168; called by muse, mutect2, varscan2
- BSG | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 152/218 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs1372990640; called by muse, mutect2
- CCDC38 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 197/254 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100717650; called by muse, mutect2, varscan2
- CCDC87 | c.1613C>A p.P538H | Missense Mutation (SNP) | VAF 224/403 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs538810937; called by muse, mutect2, varscan2
- CCT7 | c.1104G>C p.K368N | Missense Mutation (SNP) | VAF 235/447 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); catalogued as COSV99241020; called by muse, mutect2, varscan2
- CEP112 | c.690+1G>A p.X230_splice | Splice Site (SNP) | VAF 111/262 reads (42%) | catalogued as rs1203415267; called by muse, mutect2, varscan2
- CGAS | c.1268G>C p.R423T | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV100943649; called by muse, mutect2, varscan2
- CMYA5 | c.9017G>T p.S3006I | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV71404624; called by muse, mutect2, varscan2
- COL1A2 | c.2378G>T p.G793V | Missense Mutation (SNP) | VAF 84/339 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51960509, COSV51967824; called by muse, mutect2, varscan2
- CRB1 | c.2371G>T p.G791* | Nonsense Mutation (SNP) | VAF 175/206 reads (85%) | catalogued as CM155782, COSV66333514; called by muse, mutect2, varscan2
- DCTN1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.885); catalogued as rs764615912, COSV62620987; called by muse, mutect2
- DERL3 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 296/510 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs747617476; called by muse, mutect2, varscan2
- DHFR2 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 102/583 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775609912, COSV58936660; called by muse, mutect2, varscan2
- DIPK1C | c.1011C>A p.C337* | Nonsense Mutation (SNP) | VAF 86/123 reads (70%) | catalogued as COSV59725360; called by muse, mutect2, varscan2
- DNAH5 | c.12080G>T p.G4027V | Missense Mutation (SNP) | VAF 219/460 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV54249439; called by muse, mutect2, varscan2
- DOCK10 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 199/428 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.393); catalogued as COSV51373283; called by muse, mutect2, varscan2
- DYNC2H1 | c.6886G>T p.G2296C | Missense Mutation (SNP) | VAF 96/170 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62085984; called by muse, mutect2, varscan2
- EBF3 | c.1574G>A p.S525N | Missense Mutation (SNP) | VAF 236/277 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as rs982052126, COSV62472198; called by muse, mutect2, varscan2
- EIPR1 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 118/612 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775391718; called by muse, mutect2, varscan2
- ELMOD1 | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 178/303 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs373004553; called by muse, mutect2, varscan2
- EML3 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 199/354 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV53884325; called by muse, mutect2, varscan2
- ERICH1 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 142/201 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs763310568; called by muse, mutect2, varscan2
- ERICH3 | c.4250C>A p.A1417E | Missense Mutation (SNP) | VAF 266/317 reads (84%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV100443269; called by muse, mutect2, varscan2
- EVPL | c.4355G>A p.R1452Q | Missense Mutation (SNP) | VAF 166/702 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as rs1413866393; called by muse, mutect2, varscan2
- FAM86B1 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 111/407 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.076); catalogued as rs1343747997; called by muse, mutect2, varscan2
- FOXI3 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 130/556 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1427389100, COSV67916788; called by muse, mutect2, varscan2
- FOXP1 | c.1537G>A p.V513M | Missense Mutation (SNP) | VAF 143/189 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1300281537; called by muse, mutect2, varscan2
- FUT3 | c.1035G>C p.Q345H | Missense Mutation (SNP) | VAF 466/517 reads (90%) | SIFT tolerated (0.16); PolyPhen benign (0.29); catalogued as COSV54607140; called by muse, mutect2, varscan2
- GAS7 | c.725G>T p.R242L (on ENST00000432992 / NM_201433.2; = p.R102L on NM_003644.3) | Missense Mutation (SNP) | VAF 148/167 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV100097042; called by muse, mutect2, varscan2
- GOLGA6L2 | c.30C>A p.H10Q | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.194); catalogued as rs765308989; called by muse, mutect2, varscan2
- GPR176 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 140/511 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.551); catalogued as COSV54446062; called by muse, mutect2, varscan2
- GPR32 | c.480G>A p.W160* | Nonsense Mutation (SNP) | VAF 126/504 reads (25%) | catalogued as rs764470671; called by muse, mutect2, varscan2
- GRIK4 | c.2476G>T p.E826* | Nonsense Mutation (SNP) | VAF 197/347 reads (57%) | catalogued as COSV70804710; called by muse, mutect2, varscan2
- H2AC14 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV100297676; called by muse, mutect2, varscan2
- HEPH | c.3469A>G p.K1157E (on ENST00000343002; = p.K890E on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 180/204 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs760416369; called by muse, mutect2, varscan2
- IFIT3 | c.1186del p.E396Kfs*28 | Frame Shift Del (DEL) | VAF 77/251 reads (31%) | catalogued as COSV99260297; called by mutect2, pindel, varscan2
- IPO11 | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as rs1372760104; called by muse, mutect2, varscan2
- ISOC2 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 336/491 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs967027571; called by muse, mutect2, varscan2
- ITGA1 | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 112/311 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200169693; called by muse, mutect2
- ITPRID2 | c.2318A>G p.Y773C | Missense Mutation (SNP) | VAF 151/410 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs200766900; called by muse, mutect2, varscan2
- KCNA5 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 260/676 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52908892; called by muse, varscan2
- KCNK12 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 318/665 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as rs1234511570, COSV100009838; called by muse, mutect2, varscan2
- KIAA1217 | c.3848G>T p.G1283V | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1320330860; called by muse, mutect2, varscan2
- KLHL10 | c.578A>T p.D193V | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53172974; called by muse, mutect2
- LAMA1 | c.6703G>T p.G2235W | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67544000; called by mutect2, varscan2
- LCE3A | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 121/682 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); catalogued as rs763302367; called by muse, mutect2, varscan2
- LDAH | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 225/519 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.209); catalogued as rs763001302; called by muse, mutect2, varscan2
- LMX1A | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 28/704 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.453); catalogued as rs766469252, COSV99671327; called by muse, mutect2
- LRP1B | c.8961del p.T2988Lfs*30 | Frame Shift Del (DEL) | VAF 136/484 reads (28%) | catalogued as COSV67245074; called by mutect2, pindel, varscan2
- MAGEE2 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 130/320 reads (41%) | catalogued as rs746202577, COSV64897231; called by muse, mutect2, varscan2
- MAGEL2 | c.3377G>A p.C1126Y | Missense Mutation (SNP) | VAF 208/368 reads (57%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.112); catalogued as COSV58567314; called by muse, mutect2, varscan2
- MCTP1 | c.145C>A p.R49S | Missense Mutation (SNP) | VAF 360/654 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs766747520; called by muse, varscan2
- MEF2C | c.916C>G p.Q306E | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100424967; called by muse, mutect2, varscan2
- MYH11 | c.5528C>A p.S1843* | Nonsense Mutation (SNP) | VAF 135/495 reads (27%) | catalogued as COSV55556983; called by muse, mutect2, varscan2
- MYO5B | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53218957; called by muse, mutect2, varscan2
- NCAM1 | c.2563G>A p.E855K (on ENST00000316851 / NM_181351.5; = p.E845K on NM_000615.7) | Missense Mutation (SNP) | VAF 166/290 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs369107930; called by muse, mutect2, varscan2
- NELL1 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 157/223 reads (70%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1199157497, COSV54290404, COSV54327653; called by muse, mutect2, varscan2
- NIBAN3 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 133/163 reads (82%) | catalogued as rs780450113; called by muse, mutect2, varscan2
- NRP1 | c.2696A>G p.Y899C | Missense Mutation (SNP) | VAF 242/292 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769226149; called by muse, mutect2, varscan2
- NTN5 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 531/834 reads (64%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.626); catalogued as rs746645117; called by muse, mutect2, varscan2
- OR2T8 | c.16T>C p.Y6H | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100178370; called by muse, mutect2, varscan2
- OR52L1 | c.23C>A p.S8Y | Missense Mutation (SNP) | VAF 116/153 reads (76%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.576); catalogued as COSV59989749; called by muse, mutect2, varscan2
- OR5A2 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 162/287 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.095); catalogued as COSV57391985; called by muse, mutect2, varscan2
- OR5D18 | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 207/376 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV61736239; called by muse, mutect2, varscan2
- OR5K3 | c.446A>T p.Y149F | Missense Mutation (SNP) | VAF 93/458 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.162); catalogued as COSV67350725; called by muse, mutect2, varscan2
- OSMR | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 139/406 reads (34%) | catalogued as COSV57083546; called by muse, mutect2, varscan2
- OTOGL | c.4870G>A p.D1624N (on ENST00000547103; = p.D1615N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/141 reads (82%) | SIFT tolerated (0.93); PolyPhen benign (0.02); catalogued as COSV54013456; called by muse, mutect2, varscan2
- PAQR9 | c.1019C>A p.P340Q | Missense Mutation (SNP) | VAF 380/665 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs992045390; called by muse, mutect2, varscan2
- PCDH19 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 424/468 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867012022, COSV55259918; called by muse, mutect2, varscan2
- PCDHB12 | c.1466del p.S489Cfs*53 | Frame Shift Del (DEL) | VAF 173/808 reads (21%) | catalogued as COSV53397614; called by mutect2, pindel, varscan2
- PCDHB6 | c.1999C>A p.P667T | Missense Mutation (SNP) | VAF 419/760 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as rs546885437; called by muse, mutect2, varscan2
- PCDHB7 | c.1713del p.C572Afs*15 | Frame Shift Del (DEL) | VAF 210/964 reads (22%) | catalogued as COSV99176949; called by pindel, varscan2
- PEAR1 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 369/685 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747412963; called by muse, mutect2, varscan2
- PID1 | c.506G>A p.C169Y (on ENST00000354069 / NM_001330156.1; = p.C167Y on NM_017933.5) | Missense Mutation (SNP) | VAF 151/436 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766796821; called by muse, mutect2, varscan2
- PKD1 | c.3184C>T p.Q1062* | Nonsense Mutation (SNP) | VAF 83/342 reads (24%) | catalogued as CM1210862; called by muse, varscan2
- PKHD1 | c.6676A>G p.M2226V | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs751398880; called by muse, mutect2, varscan2
- PKHD1 | c.5879C>A p.T1960K | Missense Mutation (SNP) | VAF 165/293 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs534831346; called by muse, mutect2, varscan2
- PPIP5K1 | c.3550A>T p.T1184S (on ENST00000396923; = p.T1159S on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/338 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); catalogued as rs1460001095; called by muse, mutect2, varscan2
- PREP | c.149C>A p.P50H (on ENST00000369110; = p.P116H on NM_002726.5) | Missense Mutation (SNP) | VAF 173/277 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100963817; called by muse, mutect2, varscan2
- PRKAG2 | c.1236G>T p.M412I | Missense Mutation (SNP) | VAF 95/184 reads (52%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV99835439; called by muse, mutect2, varscan2
- PRM2 | c.164del p.R55Pfs*72 | Frame Shift Del (DEL) | VAF 180/667 reads (27%) | catalogued as COSV54113501; called by mutect2, pindel, varscan2
- PSG11 | c.993C>G p.F331L | Missense Mutation (SNP) | VAF 238/366 reads (65%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1178481939; called by muse, mutect2, varscan2
- PTPRO | c.1015T>A p.S339T | Missense Mutation (SNP) | VAF 97/390 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.024); catalogued as rs375448871; called by muse, mutect2, varscan2
- RFPL4B | c.84C>A p.H28Q | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773462376; called by muse, mutect2, varscan2
- RFX7 | c.347A>G p.N116S (on ENST00000559447 / NM_001368074.1; = p.N213S on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/323 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1489534308; called by muse, mutect2, varscan2
- RGS6 | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 216/406 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59586409; called by muse, mutect2, varscan2
- RIBC1 | c.160C>A p.R54S | Missense Mutation (SNP) | VAF 218/247 reads (88%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV51448170; called by muse, mutect2, varscan2
- RP1L1 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 154/213 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66756179, COSV66759892; called by muse, mutect2, varscan2
- RUNDC3B | c.265G>C p.A89P | Missense Mutation (SNP) | VAF 113/211 reads (54%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV99714828; called by muse, mutect2, varscan2
- RYR3 | c.10525C>T p.H3509Y (on ENST00000389232; = p.H3510Y on NM_001036.6) | Missense Mutation (SNP) | VAF 83/165 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs767621712, COSV66790427; called by muse, mutect2, varscan2
- SDSL | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 239/278 reads (86%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs751307425; called by muse, mutect2, varscan2
- SETX | c.1682A>T p.K561M | Missense Mutation (SNP) | VAF 180/229 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99809434; called by muse, mutect2, varscan2
- SIRT2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 86/409 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs926292218, COSV50874936; called by muse, mutect2, varscan2
- SLC1A6 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs769743084, COSV55667703; called by muse, mutect2, varscan2
- SNAPC4 | c.2175G>C p.Q725H | Missense Mutation (SNP) | VAF 206/494 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.459); catalogued as rs201265450; called by muse, mutect2, varscan2
- SSH2 | c.3216C>A p.H1072Q | Missense Mutation (SNP) | VAF 228/297 reads (77%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.024); catalogued as COSV52175653; called by muse, mutect2, varscan2
- SSTR1 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 347/686 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV57455597; called by muse, mutect2, varscan2
- TANGO2 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 184/324 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100530030; called by muse, mutect2, varscan2
- TBX15 | c.562G>T p.A188S (on ENST00000369429 / NM_001330677.2; = p.A82S on NM_152380.3) | Missense Mutation (SNP) | VAF 165/219 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99254281; called by muse, mutect2, varscan2
- TENM2 | c.3268T>C p.S1090P (on ENST00000518659 / NM_001122679.2; = p.S858P on NM_001080428.3) | Missense Mutation (SNP) | VAF 139/453 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.391); catalogued as rs367950355; called by muse, mutect2, varscan2
- TERF1 | c.1178C>G p.S393C (on ENST00000276603 / NM_017489.3; = p.S373C on NM_003218.4) | Missense Mutation (SNP) | VAF 131/248 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1257013963; called by muse, mutect2, varscan2
- TGM1 | c.1936G>T p.V646L | Missense Mutation (SNP) | VAF 155/465 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as rs765539126; called by muse, mutect2, varscan2
- TRIML1 | c.556C>A p.H186N | Missense Mutation (SNP) | VAF 58/498 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV100205689; called by muse, mutect2
- TRPM4 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53260289; called by muse, mutect2, varscan2
- TTN | c.10595C>T p.P3532L (on ENST00000591111; = p.P3486L on NM_003319.4) | Missense Mutation (SNP) | VAF 125/379 reads (33%) | catalogued as rs727503662; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- TULP1 | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 111/428 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV100003869; called by muse, mutect2, varscan2
- USP12 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.948); catalogued as COSV56658490; called by muse, mutect2, varscan2
- ZAN | c.6583G>A p.G2195R | Missense Mutation (SNP) | VAF 84/324 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1347976699; called by muse, mutect2, varscan2
- ZNF454 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 110/346 reads (32%) | catalogued as rs1217144684, COSV100194890; called by muse, mutect2, varscan2
- ZNF501 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 106/267 reads (40%) | catalogued as rs758058321; called by muse, mutect2, varscan2
- ZNF790 | c.224G>A p.C75Y | Missense Mutation (SNP) | VAF 119/346 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1285339090; called by muse, mutect2, varscan2
- ABCA13 | c.1318G>C p.A440P | Missense Mutation (SNP) | VAF 161/305 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- ABCA3 | c.1843G>C p.D615H | Missense Mutation (SNP) | VAF 120/426 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCD2 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 171/449 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ACACB | c.3306G>C p.E1102D | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM2A | c.1698G>T p.K566N (on ENST00000219054; = p.K487N on NM_001308169.2) | Missense Mutation (SNP) | VAF 75/330 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- ACSM2A | c.1699G>T p.E567* (on ENST00000219054; = p.E488* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 74/329 reads (22%) | called by muse, mutect2, varscan2
- ACTC1 | c.878A>G p.K293R | Missense Mutation (SNP) | VAF 203/330 reads (62%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ACY3 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 162/323 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ADAM20 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 217/632 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ADAMTS7 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 158/533 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AHCY | c.914A>G p.E305G | Missense Mutation (SNP) | VAF 283/871 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AIM2 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 200/597 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- AL162417.1 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 208/437 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALK | c.3794T>A p.V1265E | Missense Mutation (SNP) | VAF 205/486 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ANK2 | c.9C>G p.N3K | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ANKFN1 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 210/235 reads (89%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANKFN1 | c.1748C>A p.P583Q | Missense Mutation (SNP) | VAF 206/231 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AP2A2 | c.1731G>C p.Q577H | Missense Mutation (SNP) | VAF 349/426 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF1 | c.2413G>T p.A805S | Missense Mutation (SNP) | VAF 113/205 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP44 | c.461C>A p.T154N | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ARID1A | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 407/508 reads (80%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); called by muse, varscan2
- ASB1 | c.38del p.P13Rfs*8 | Frame Shift Del (DEL) | VAF 142/561 reads (25%) | called by mutect2, pindel, varscan2
- ASB6 | c.135G>C p.E45D | Missense Mutation (SNP) | VAF 156/182 reads (86%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATM | c.6876G>C p.Q2292H | Missense Mutation (SNP) | VAF 84/335 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ATN1 | c.1352_1359del p.L451Qfs*70 | Frame Shift Del (DEL) | VAF 91/589 reads (15%) | called by mutect2, pindel, varscan2
- BDP1 | c.4768_4784del p.Q1590* | Frame Shift Del (DEL) | VAF 95/260 reads (37%) | called by mutect2, pindel, varscan2
- BIRC6 | c.2724G>T p.Q908H | Missense Mutation (SNP) | VAF 159/373 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BRWD1 | c.6794G>A p.R2265K | Missense Mutation (SNP) | VAF 105/880 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- BSG | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 150/213 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BTN1A1 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 75/363 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C10orf105 | c.234C>A p.H78Q | Missense Mutation (SNP) | VAF 349/433 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- C19orf81 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 273/404 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C20orf203 | c.570del p.S191Rfs*117 | Frame Shift Del (DEL) | VAF 66/518 reads (13%) | called by mutect2, pindel, varscan2
- C20orf96 | c.262A>C p.K88Q (on ENST00000360321 / NM_153269.3; = p.K87Q on NM_080571.1) | Missense Mutation (SNP) | VAF 154/455 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C4orf47 | c.899A>T p.N300I | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CACNA1S | c.1835C>A p.T612K | Missense Mutation (SNP) | VAF 91/314 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA2D4 | c.1108G>C p.V370L | Missense Mutation (SNP) | VAF 261/554 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- CACNG3 | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 221/389 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- CAD | c.1713G>T p.R571S | Missense Mutation (SNP) | VAF 274/579 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBFB | c.177_179delinsAT p.T60* | Frame Shift Del (DEL) | VAF 124/300 reads (41%) | called by pindel, varscan2*
- CD1B | c.395T>A p.L132Q | Missense Mutation (SNP) | VAF 331/699 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- CD47 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CD8A | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 279/584 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- CDH12 | c.1737G>C p.Q579H | Missense Mutation (SNP) | VAF 104/708 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CDHR2 | c.3374A>T p.D1125V | Missense Mutation (SNP) | VAF 119/359 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.163); called by muse, varscan2
- CDK5R2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 254/632 reads (40%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- CFAP61 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 164/374 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHAT | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 190/249 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD7 | c.1405A>T p.R469W | Missense Mutation (SNP) | VAF 78/307 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNGA3 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 306/777 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CNTNAP5 | c.2090C>G p.T697S | Missense Mutation (SNP) | VAF 165/324 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- COL20A1 | c.3383T>C p.V1128A | Missense Mutation (SNP) | VAF 303/766 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- COL6A5 | c.2663G>T p.G888V | Missense Mutation (SNP) | VAF 330/565 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- COL6A5 | c.5066G>C p.G1689A | Missense Mutation (SNP) | VAF 149/505 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACD | c.1534_1536del p.A512del | In Frame Del (DEL) | VAF 104/432 reads (24%) | called by pindel, varscan2
- DACT3 | c.892_896del p.S298Afs*52 | Frame Shift Del (DEL) | VAF 64/446 reads (14%) | called by mutect2, pindel, varscan2
- DCAF11 | c.1491G>C p.K497N | Missense Mutation (SNP) | VAF 20/594 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.031); called by muse, mutect2
- DCTN1 | c.1632G>C p.R544S | Missense Mutation (SNP) | VAF 228/537 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DDX27 | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 78/392 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- DEFB104A | c.163T>A p.Y55N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.134); called by mutect2, varscan2
- DIP2B | c.2369del p.P790Hfs*11 | Frame Shift Del (DEL) | VAF 131/379 reads (35%) | called by mutect2, pindel, varscan2
- DLGAP3 | c.2000+1G>T p.X667_splice | Splice Site (SNP) | VAF 120/155 reads (77%) | called by mutect2, varscan2
- DLGAP3 | c.2000G>T p.R667M | Missense Mutation (SNP) | VAF 120/155 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- DNAH17 | c.4309A>T p.M1437L | Missense Mutation (SNP) | VAF 477/537 reads (89%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH6 | c.3205G>A p.A1069T | Missense Mutation (SNP) | VAF 205/460 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DNHD1 | c.8759A>T p.E2920V | Missense Mutation (SNP) | VAF 252/306 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- DNTT | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 102/131 reads (78%) | called by muse, mutect2, varscan2
- DSEL | c.305G>T p.S102I | Missense Mutation (SNP) | VAF 140/192 reads (73%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- DSG1 | c.2984G>T p.G995V | Missense Mutation (SNP) | VAF 258/319 reads (81%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- DZIP3 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1153A>T p.R385* | Nonsense Mutation (SNP) | VAF 359/632 reads (57%) | called by muse, mutect2, varscan2
- ENPEP | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 119/562 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- F2RL3 | c.195C>A p.D65E | Missense Mutation (SNP) | VAF 339/416 reads (81%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAF2 | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 229/417 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAT3 | c.1431T>A p.Y477* | Nonsense Mutation (SNP) | VAF 183/318 reads (58%) | called by muse, mutect2, varscan2
- FCRL4 | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 229/618 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FH | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 160/282 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG2 | c.1407T>A p.H469Q | Missense Mutation (SNP) | VAF 244/695 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FUT11 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 418/506 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAS2L1 | c.1943C>G p.P648R | Missense Mutation (SNP) | VAF 148/559 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GBX2 | c.751C>G p.R251G | Missense Mutation (SNP) | VAF 189/677 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GC | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 80/344 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCG | c.311C>A p.T104N | Missense Mutation (SNP) | VAF 229/426 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GCNA | c.1556A>T p.D519V | Missense Mutation (SNP) | VAF 196/215 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- GDF3 | c.834G>C p.W278C | Missense Mutation (SNP) | VAF 207/441 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GORAB | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 152/305 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- GPR15 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 367/639 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR83 | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 181/329 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPRIN1 | c.2256del p.E753Sfs*74 | Frame Shift Del (DEL) | VAF 143/621 reads (23%) | called by mutect2, pindel, varscan2
- GRIN2B | c.3479A>G p.D1160G | Missense Mutation (SNP) | VAF 161/661 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GRM3 | c.2520C>G p.H840Q | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- GRM5 | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 119/393 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIPK1 | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 157/189 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXC13 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 267/612 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR3E | c.467T>C p.M156T (on ENST00000415389 / NM_001256613.1; = p.M171T on NM_182589.2) | Missense Mutation (SNP) | VAF 216/641 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- IGHMBP2 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 103/206 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGKV2-28 | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 57/224 reads (25%) | called by muse, mutect2, varscan2
- IGLV5-37 | c.138C>A p.D46E | Missense Mutation (SNP) | VAF 167/292 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IL22 | c.95C>G p.A32G | Missense Mutation (SNP) | VAF 176/431 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ITGA2 | c.2141G>T p.R714M | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGAX | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 99/416 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1210 | c.2583C>G p.N861K | Missense Mutation (SNP) | VAF 277/303 reads (91%) | SIFT tolerated (0.1); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- KIR2DL4 | c.940A>T p.M314L (on ENST00000396284; = p.M240L on NM_001080770.2) | Missense Mutation (SNP) | VAF 105/463 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- KLF14 | c.584A>G p.H195R | Missense Mutation (SNP) | VAF 381/642 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- KLHL24 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 182/553 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LARGE2 | c.492_492+14del p.X164_splice | Splice Site (DEL) | VAF 85/445 reads (19%) | called by mutect2, pindel, varscan2
- LGSN | c.737G>A p.G246D | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- LIPI | c.1179T>A p.Y393* | Nonsense Mutation (SNP) | VAF 86/184 reads (47%) | called by muse, mutect2, varscan2
- LMNA | c.1600A>G p.T534A | Missense Mutation (SNP) | VAF 62/408 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LPCAT3 | c.408C>G p.N136K | Missense Mutation (SNP) | VAF 137/360 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- LRRC70 | c.901A>T p.N301Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MACF1 | c.19860G>T p.L6620F (on ENST00000372915; = p.L4665F on NM_012090.5) | Missense Mutation (SNP) | VAF 204/253 reads (81%) | called by muse, mutect2, varscan2
- MAGEL2 | c.2770G>T p.V924F | Missense Mutation (SNP) | VAF 117/387 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP3K19 | c.1426C>A p.P476T | Missense Mutation (SNP) | VAF 159/433 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAP3K7 | c.909G>C p.Q303H | Missense Mutation (SNP) | VAF 114/221 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MAST4 | c.7291G>T p.A2431S (on ENST00000403625 / NM_001164664.2; = p.A2242S on NM_015183.3) | Missense Mutation (SNP) | VAF 172/411 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MBNL1 | c.963del p.Q321Hfs*4 (on ENST00000282486 / NM_207293.2; = p.Q303Hfs*4 on NM_021038.5 and 10 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 43/432 reads (10%) | called by mutect2, pindel, varscan2
- MCF2 | c.1700G>A p.C567Y | Missense Mutation (SNP) | VAF 125/138 reads (91%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- MED12 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 202/226 reads (89%) | SIFT tolerated (0.5); PolyPhen benign (0.023); called by muse, varscan2
- MFGE8 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 81/280 reads (29%) | called by muse, mutect2, varscan2
- MGAM2 | c.4361T>C p.V1454A | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MGAT5B | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 88/468 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MMP12 | c.83A>T p.N28I | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- MS4A4A | c.498C>A p.N166K | Missense Mutation (SNP) | VAF 200/351 reads (57%) | SIFT tolerated (0.57); PolyPhen benign (0.096); called by muse, mutect2
- MUC17 | c.6035C>A p.T2012N | Missense Mutation (SNP) | VAF 66/291 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MXRA8 | c.533_547del p.R178_A182del | In Frame Del (DEL) | VAF 163/452 reads (36%) | called by mutect2, pindel, varscan2
- MYO1D | c.1402G>T p.D468Y | Missense Mutation (SNP) | VAF 164/207 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MZF1 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 463/829 reads (56%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- NCS1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 175/215 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NELFCD | c.60C>A p.D20E (on ENST00000602795; = p.D2E on NM_198976.4) | Missense Mutation (SNP) | VAF 186/408 reads (46%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NF1 | c.7295A>G p.N2432S (on ENST00000358273 / NM_001042492.3; = p.N2411S on NM_000267.3) | Missense Mutation (SNP) | VAF 137/164 reads (84%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NOTCH1 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 89/256 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRP2 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NSUN2 | c.1084A>T p.T362S | Missense Mutation (SNP) | VAF 181/513 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NUF2 | c.1149A>T p.K383N | Missense Mutation (SNP) | VAF 138/279 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- OCA2 | c.2402G>T p.G801V | Missense Mutation (SNP) | VAF 221/412 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OLFML2A | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 252/318 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OOSP2 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 167/279 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OOSP4A | c.480-1G>T p.X160_splice | Splice Site (SNP) | VAF 61/264 reads (23%) | called by muse, mutect2, varscan2
- OR2T4 | c.828C>A p.H276Q | Missense Mutation (SNP) | VAF 409/741 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR4N2 | c.325G>C p.G109R | Missense Mutation (SNP) | VAF 447/859 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- OR5AC2 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 114/538 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5AK2 | c.885G>C p.K295N | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- OR5F1 | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR5H15 | c.17C>A p.A6E | Missense Mutation (SNP) | VAF 214/400 reads (54%) | SIFT tolerated (0.84); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR7A17 | c.866T>G p.I289S | Missense Mutation (SNP) | VAF 126/153 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR8H3 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 167/336 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPPA2 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 392/756 reads (52%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PASK | c.2905G>T p.V969L | Missense Mutation (SNP) | VAF 124/339 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PBXIP1 | c.666T>C p.T222= | Splice Region (SNP) | VAF 173/483 reads (36%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 190/657 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.196); called by muse, mutect2
- PCGF2 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 131/165 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PCYT1B | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 168/181 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PGR | c.2232dup p.D745* | Frame Shift Ins (INS) | VAF 58/256 reads (23%) | called by mutect2, pindel, varscan2
- PIK3C2B | c.2585G>T p.S862I | Missense Mutation (SNP) | VAF 310/519 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PLCB3 | c.3636C>G p.H1212Q | Missense Mutation (SNP) | VAF 165/601 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- PLD4 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 268/606 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- PLEC | c.2735A>T p.N912I (on ENST00000322810 / NM_201380.4; = p.N802I on NM_000445.5) | Missense Mutation (SNP) | VAF 252/470 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PLEKHA2 | c.1061G>T p.W354L | Missense Mutation (SNP) | VAF 223/638 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLPPR3 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 115/167 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- POLQ | c.5183T>A p.I1728K | Missense Mutation (SNP) | VAF 65/308 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- POM121L12 | c.717C>A p.S239R | Missense Mutation (SNP) | VAF 187/566 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PPFIA1 | c.2426G>T p.R809L | Missense Mutation (SNP) | VAF 136/475 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PPP1R12C | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 346/514 reads (67%) | called by mutect2, varscan2
- PPP4R3C | c.1140G>T p.R380S | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PREP | c.1246C>G p.P416A (on ENST00000369110; = p.P482A on NM_002726.5) | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRA | c.1246A>T p.T416S | Missense Mutation (SNP) | VAF 221/576 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.009); called by mutect2, varscan2
- PTPRD | c.4642C>A p.P1548T | Missense Mutation (SNP) | VAF 124/162 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- R3HDM1 | c.845C>G p.S282C | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB11FIP1 | c.25C>G p.R9G | Missense Mutation (SNP) | VAF 121/653 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAG2 | c.1541T>G p.L514W | Missense Mutation (SNP) | VAF 98/486 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- RFXANK | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 246/309 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- RGPD1 | c.1307G>A p.W436* (on ENST00000409776; = p.W444* on NM_001024457.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 81/477 reads (17%) | called by muse, mutect2, varscan2
- RIT2 | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 176/216 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RNF145 | c.1691G>T p.W564L (on ENST00000424310 / NM_001199383.2; = p.W592L on NM_144726.2) | Missense Mutation (SNP) | VAF 195/330 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RP1 | c.3944G>T p.C1315F | Missense Mutation (SNP) | VAF 95/358 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- RSAD2 | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 78/382 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SALL1 | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 254/574 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- SAMD9 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 235/425 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SBSN | c.1084G>T p.G362W | Missense Mutation (SNP) | VAF 327/904 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SBSN | c.810G>T p.E270D | Missense Mutation (SNP) | VAF 388/1153 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, varscan2
- SCN1A | c.4074G>T p.W1358C (on ENST00000303395 / NM_001202435.3; = p.W1347C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/376 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCYL3 | c.1386A>G p.I462M | Missense Mutation (SNP) | VAF 77/469 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEMA3D | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 143/283 reads (51%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD1A | c.4094G>A p.G1365E | Missense Mutation (SNP) | VAF 368/708 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- SETD2 | c.7462C>T p.P2488S | Missense Mutation (SNP) | VAF 178/240 reads (74%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- SLC8A2 | c.2428T>A p.C810S | Missense Mutation (SNP) | VAF 134/608 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2
- SORBS2 | c.1166A>T p.N389I | Missense Mutation (SNP) | VAF 121/813 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SPAG17 | c.4882G>C p.E1628Q | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPIDR | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 95/313 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SRRM3 | c.1001C>A p.P334Q | Missense Mutation (SNP) | VAF 299/487 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- STXBP5 | c.2211G>T p.K737N | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SYNE1 | c.20644T>G p.S6882A (on ENST00000367255 / NM_182961.4; = p.S6811A on NM_033071.3) | Missense Mutation (SNP) | VAF 83/333 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYT4 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 158/211 reads (75%) | SIFT tolerated (0.53); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SZT2 | c.7796C>T p.S2599F (on ENST00000634258 / NM_001365999.1; = p.S2542F on NM_015284.4) | Missense Mutation (SNP) | VAF 259/319 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- TADA2A | c.1001_1015del p.Q334_R338del | In Frame Del (DEL) | VAF 41/147 reads (28%) | called by mutect2, pindel, varscan2
- TBCA | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- TDO2 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 222/310 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TDRD12 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 124/314 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TDRD15 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 130/330 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- TEX26 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 72/89 reads (81%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TFR2 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 277/470 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- THBS1 | c.1575G>C p.Q525H | Missense Mutation (SNP) | VAF 214/412 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- THSD7B | c.4119C>G p.C1373W (on ENST00000272643; = p.C1371W on NM_001316349.2) | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM132E | c.1997T>A p.L666Q (on ENST00000321639; = p.L756Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 272/358 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2
- TMEM132E | c.1999G>A p.D667N (on ENST00000321639; = p.D757N on NM_001304438.2) | Missense Mutation (SNP) | VAF 274/356 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2
- TMIGD1 | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 202/231 reads (87%) | SIFT tolerated (0.14); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- TNIK | c.1804G>T p.G602* | Nonsense Mutation (SNP) | VAF 65/401 reads (16%) | called by muse, mutect2, varscan2
- TNR | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 236/479 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TNS2 | c.2120T>G p.L707R (on ENST00000314250 / NM_170754.4; = p.L717R on NM_015319.2) | Missense Mutation (SNP) | VAF 286/687 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TOP2B | c.4649C>G p.S1550C (on ENST00000264331 / NM_001330700.2; = p.S1545C on NM_001068.3) | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TP53 | c.618_619del p.D207* | Frame Shift Del (DEL) | VAF 191/247 reads (77%) | called by mutect2, pindel*, varscan2*
- TRAV19 | c.299C>A p.T100K | Missense Mutation (SNP) | VAF 294/537 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TRAV8-1 | c.160T>A p.W54R | Missense Mutation (SNP) | VAF 208/568 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAV8-6 | c.325T>A p.F109I | Missense Mutation (SNP) | VAF 125/345 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TRBV5-1 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 223/405 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- TRIM10 | c.837G>T p.R279S | Missense Mutation (SNP) | VAF 290/481 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIML1 | c.558C>A p.H186Q | Missense Mutation (SNP) | VAF 58/510 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- TRIML2 | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 87/650 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TRMT11 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRRAP | c.7985A>T p.Q2662L (on ENST00000359863 / NM_001244580.1; = p.Q2644L on NM_003496.3) | Missense Mutation (SNP) | VAF 103/438 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.54025T>C p.Y18009H (on ENST00000591111; = p.Y10585H on NM_003319.4) | Missense Mutation (SNP) | VAF 133/411 reads (32%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.10594C>A p.P3532T (on ENST00000591111; = p.P3486T on NM_003319.4) | Missense Mutation (SNP) | VAF 127/382 reads (33%) | called by muse, mutect2, varscan2
- TTYH2 | c.1135del p.A379Lfs*28 | Frame Shift Del (DEL) | VAF 153/444 reads (34%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.1117A>G p.I373V | Missense Mutation (SNP) | VAF 104/210 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.181); called by muse, varscan2
- TUT4 | c.2180A>T p.K727M | Missense Mutation (SNP) | VAF 216/262 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- USP8 | c.1915G>C p.A639P | Missense Mutation (SNP) | VAF 99/189 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP9Y | c.4837G>A p.V1613I | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- UTY | c.1203G>T p.W401C | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- WNK1 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 159/403 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WNK3 | c.3508G>T p.D1170Y | Missense Mutation (SNP) | VAF 211/232 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZBED3 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 175/456 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.025); called by muse, mutect2
- ZBTB4 | c.974A>G p.K325R | Missense Mutation (SNP) | VAF 271/325 reads (83%) | SIFT tolerated (0.44); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ZGRF1 | c.5765G>T p.G1922V | Missense Mutation (SNP) | VAF 141/209 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZGRF1 | c.5764G>T p.G1922* | Nonsense Mutation (SNP) | VAF 130/194 reads (67%) | called by muse, varscan2
- ZGRF1 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 333/492 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZMAT4 | c.637T>A p.Y213N | Missense Mutation (SNP) | VAF 60/352 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF614 | c.899G>C p.R300P | Missense Mutation (SNP) | VAF 96/433 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- ZNF664 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 91/324 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- ABCC12 | c.3066C>T p.L1022= | Silent (SNP) | VAF 199/244 reads (82%) | catalogued as COSV60912686; called by muse, mutect2, varscan2
- ALK | c.2505G>A p.P835= | Silent (SNP) | VAF 66/372 reads (18%) | catalogued as rs201700728; ClinVar: likely benign; called by muse, mutect2, varscan2
- AMPH | c.1590C>T p.L530= | Silent (SNP) | VAF 70/291 reads (24%) | catalogued as rs201328417, COSV100340349, COSV57736176; called by muse, mutect2, varscan2
- ANKRD35 | c.1086C>G p.L362= | Silent (SNP) | VAF 128/787 reads (16%) | called by muse, mutect2, varscan2
- ANKRD54 | c.303C>G p.L101= | Silent (SNP) | VAF 135/462 reads (29%) | catalogued as COSV53236953; called by muse, mutect2, varscan2
- ARMH1 | c.1233C>T p.S411= | Silent (SNP) | VAF 193/245 reads (79%) | called by muse, mutect2, varscan2
- ATF6B | c.273A>G p.P91= | Silent (SNP) | VAF 187/338 reads (55%) | catalogued as rs1008079847; called by muse, mutect2, varscan2
- BCL11B | c.567C>T p.R189= | Silent (SNP) | VAF 395/902 reads (44%) | catalogued as rs922277828; called by muse, mutect2, varscan2
- BTNL3 | c.1335C>A p.I445= | Silent (SNP) | VAF 95/365 reads (26%) | called by muse, mutect2, varscan2
- CACNA1H | c.2034C>A p.G678= | Silent (SNP) | VAF 143/525 reads (27%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.1824C>A p.I608= | Silent (SNP) | VAF 165/399 reads (41%) | called by muse, mutect2, varscan2
- CAMTA1 | c.2190C>A p.A730= | Silent (SNP) | VAF 311/382 reads (81%) | called by muse, mutect2, varscan2
- CAND1 | c.2955G>C p.V985= | Silent (SNP) | VAF 74/385 reads (19%) | catalogued as COSV73389578; called by muse, mutect2, varscan2
- CAPN1 | c.1707C>T p.I569= | Silent (SNP) | VAF 111/359 reads (31%) | catalogued as rs1355860807; called by muse, mutect2, varscan2
- CCR9 | c.171C>T p.L57= (on ENST00000357632 / NM_031200.3; = p.L45= on NM_006641.4) | Silent (SNP) | VAF 236/290 reads (81%) | catalogued as rs537966588; called by muse, varscan2
- CD163L1 | c.3672T>G p.S1224= | Silent (SNP) | VAF 176/426 reads (41%) | called by muse, mutect2, varscan2
- CFAP161 | c.604T>C p.L202= | Silent (SNP) | VAF 160/274 reads (58%) | catalogued as rs984111620; called by muse, mutect2, varscan2
- CHRNA4 | c.1365C>A p.T455= | Silent (SNP) | VAF 293/747 reads (39%) | called by muse, mutect2, varscan2
- CLEC18B | c.756C>A p.P252= | Silent (SNP) | VAF 55/389 reads (14%) | called by muse, mutect2, varscan2
- CLPS | c.276C>T p.I92= | Silent (SNP) | VAF 109/445 reads (24%) | catalogued as rs765091326; called by muse, mutect2, varscan2
- CLVS1 | c.240C>A p.L80= | Silent (SNP) | VAF 105/395 reads (27%) | catalogued as COSV100369725; called by muse, mutect2, varscan2
- CPD | c.3753C>G p.L1251= | Silent (SNP) | VAF 80/225 reads (36%) | catalogued as rs758360971, COSV56714100; called by muse, mutect2, varscan2
- CSN2 | c.324C>T p.V108= | Silent (SNP) | VAF 131/419 reads (31%) | called by muse, mutect2, varscan2
- CYP21A2 | c.1191G>A p.T397= | Silent (SNP) | VAF 97/741 reads (13%) | catalogued as rs775982691, COSV64484917; called by muse, mutect2, varscan2
- DCDC2C | c.483C>T p.S161= | Silent (SNP) | VAF 68/271 reads (25%) | catalogued as rs960819352; called by muse, mutect2, varscan2
- DENND2A | c.426C>A p.G142= | Silent (SNP) | VAF 312/533 reads (59%) | called by muse, mutect2, varscan2
- DHX36 | c.2508T>C p.C836= | Silent (SNP) | VAF 158/457 reads (35%) | called by muse, mutect2, varscan2
- ESPN | c.414C>T p.G138= | Silent (SNP) | VAF 286/324 reads (88%) | catalogued as rs751089572, COSV100911531; called by muse, mutect2, varscan2
- ESRRB | c.1198C>A p.R400= | Silent (SNP) | VAF 227/660 reads (34%) | called by muse, mutect2
- EXPH5 | c.5256G>T p.L1752= | Silent (SNP) | VAF 90/333 reads (27%) | called by muse, mutect2, varscan2
- F12 | c.1536G>C p.A512= | Silent (SNP) | VAF 76/300 reads (25%) | called by muse, mutect2, varscan2
- FAM221A | c.16T>C p.L6= | Silent (SNP) | VAF 198/271 reads (73%) | catalogued as rs775824411; called by muse, mutect2, varscan2
- FANCL | c.1127G>A p.*376= | Silent (SNP) | VAF 20/162 reads (12%) | called by muse, mutect2, varscan2
- FECH | c.330C>T p.F110= | Silent (SNP) | VAF 138/173 reads (80%) | called by muse, mutect2, varscan2
- FOXP2 | c.219G>A p.L73= | Silent (SNP) | VAF 183/351 reads (52%) | called by muse, mutect2, varscan2
- GAB4 | c.279C>A p.T93= | Silent (SNP) | VAF 92/373 reads (25%) | catalogued as COSV68754325; called by muse, mutect2, varscan2
- GBP1 | c.624G>A p.L208= | Silent (SNP) | VAF 144/166 reads (87%) | catalogued as COSV65084727; called by muse, mutect2, varscan2
- HCN4 | c.2346G>T p.L782= | Silent (SNP) | VAF 176/592 reads (30%) | catalogued as rs939117369; called by muse, mutect2, varscan2
- HDAC7 | c.51C>T p.P17= (on ENST00000427332; = p.P56= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 367/915 reads (40%) | called by muse, mutect2, varscan2
- HEATR5B | c.1002A>G p.V334= | Silent (SNP) | VAF 219/445 reads (49%) | called by muse, mutect2, varscan2
- HELT | c.378C>A p.A126= | Silent (SNP) | VAF 1023/1273 reads (80%) | catalogued as rs759268394; called by muse, mutect2, varscan2
- HPF1 | c.6C>G p.V2= | Silent (SNP) | VAF 147/870 reads (17%) | catalogued as rs765737535; called by muse, mutect2, varscan2
- HTR1A | c.504T>C p.S168= | Silent (SNP) | VAF 134/335 reads (40%) | called by muse, varscan2
- ICE2 | c.576C>T p.F192= | Silent (SNP) | VAF 51/219 reads (23%) | called by muse, mutect2, varscan2
- IGHV5-51 | c.36T>G p.A12= | Silent (SNP) | VAF 184/424 reads (43%) | called by muse, mutect2, varscan2
- IL18R1 | c.375A>G p.V125= | Silent (SNP) | VAF 37/189 reads (20%) | called by muse, mutect2, varscan2
- KCNJ5 | c.414C>T p.S138= | Silent (SNP) | VAF 100/468 reads (21%) | catalogued as rs149219318; called by muse, mutect2, varscan2
- KIAA1549L | c.3243G>T p.R1081= (on ENST00000321505; = p.R1378= on NM_012194.3) | Silent (SNP) | VAF 264/544 reads (49%) | called by muse, mutect2, varscan2
- KIF21B | c.1986G>C p.T662= | Silent (SNP) | VAF 131/478 reads (27%) | catalogued as rs746573596, COSV100144524, COSV59758706; called by muse, mutect2, varscan2
- KLHL25 | c.339C>T p.N113= | Silent (SNP) | VAF 82/346 reads (24%) | catalogued as rs376662836; called by muse, varscan2
- KLHL30 | c.372C>T p.R124= | Silent (SNP) | VAF 223/601 reads (37%) | called by muse, mutect2, varscan2
- KMT2B | c.2917C>T p.L973= | Silent (SNP) | VAF 291/794 reads (37%) | catalogued as COSV99720340; called by muse, mutect2, varscan2
- KRTAP5-10 | c.135C>T p.P45= | Silent (SNP) | VAF 204/602 reads (34%) | catalogued as rs747606675; called by mutect2, varscan2
- MARCHF6 | c.2709A>T p.P903= | Silent (SNP) | VAF 153/443 reads (35%) | called by muse, mutect2, varscan2
- MARK2 | c.1716C>T p.A572= (on ENST00000402010 / NM_001039469.2; = p.A517= on NM_004954.5) | Silent (SNP) | VAF 296/505 reads (59%) | called by muse, mutect2, varscan2
- MON2 | c.5043A>G p.E1681= | Silent (SNP) | VAF 144/370 reads (39%) | called by muse, mutect2, varscan2
- MRGPRF | c.168G>A p.L56= | Silent (SNP) | VAF 142/469 reads (30%) | catalogued as rs779485318; called by muse, mutect2, varscan2
- MRPL45 | c.540C>G p.T180= | Silent (SNP) | VAF 226/285 reads (79%) | catalogued as rs774079302; called by muse, mutect2, varscan2
- MSGN1 | c.45G>A p.L15= | Silent (SNP) | VAF 180/436 reads (41%) | called by muse, mutect2, varscan2
- MUC4 | c.11610C>A p.A3870= | Silent (SNP) | VAF 265/913 reads (29%) | called by muse, mutect2, varscan2
- MUC4 | c.2049T>A p.P683= | Silent (SNP) | VAF 405/1245 reads (33%) | called by muse, mutect2, varscan2
- MYLK3 | c.1302C>T p.D434= | Silent (SNP) | VAF 340/421 reads (81%) | catalogued as rs202183804, COSV67367379; called by muse, mutect2, varscan2
- MYO9A | c.189A>G p.L63= | Silent (SNP) | VAF 134/275 reads (49%) | called by muse, mutect2, varscan2
- NDUFA2 | c.225G>T p.T75= | Silent (SNP) | VAF 101/403 reads (25%) | catalogued as CD165997, COSV52799166; called by muse, mutect2, varscan2
- NEFM | c.1899A>T p.S633= | Silent (SNP) | VAF 151/233 reads (65%) | called by muse, mutect2, varscan2
- NINJ1 | c.234G>A p.V78= | Silent (SNP) | VAF 137/367 reads (37%) | called by muse, mutect2, varscan2
- NOD1 | c.1656G>T p.G552= | Silent (SNP) | VAF 265/329 reads (81%) | catalogued as rs998329569; called by muse, mutect2, varscan2
- NRXN3 | c.681A>G p.Q227= (on ENST00000557594 / NM_001272020.2; = p.Q859= on NM_004796.6) | Silent (SNP) | VAF 97/588 reads (16%) | catalogued as rs1376714407; called by muse, mutect2, varscan2
- NXPH3 | c.195C>T p.L65= | Silent (SNP) | VAF 725/802 reads (90%) | catalogued as COSV60872339; called by muse, mutect2, varscan2
- OR2AG2 | c.564C>A p.A188= | Silent (SNP) | VAF 206/240 reads (86%) | called by mutect2, varscan2
- OR6C1 | c.918T>C p.T306= | Silent (SNP) | VAF 112/254 reads (44%) | called by muse, mutect2, varscan2
- OTUD6A | c.327G>A p.Q109= | Silent (SNP) | VAF 370/421 reads (88%) | called by muse, mutect2, varscan2
- P3H2 | c.1248C>T p.N416= | Silent (SNP) | VAF 65/614 reads (11%) | catalogued as rs374730144; called by muse, mutect2, varscan2
- PADI4 | c.54G>T p.V18= | Silent (SNP) | VAF 204/241 reads (85%) | called by muse, mutect2, varscan2
- PAPPA2 | c.1215T>C p.S405= | Silent (SNP) | VAF 418/764 reads (55%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.1032C>A p.A344= | Silent (SNP) | VAF 218/393 reads (55%) | called by muse, mutect2, varscan2
- PLD5 | c.712T>C p.L238= (on ENST00000442594; = p.L176= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 185/314 reads (59%) | catalogued as COSV59169614; called by muse, mutect2, varscan2
- POPDC3 | c.360G>T p.G120= | Silent (SNP) | VAF 101/351 reads (29%) | catalogued as COSV54643652; called by muse, mutect2, varscan2
- POTEI | c.2880G>T p.A960= | Silent (SNP) | VAF 153/352 reads (43%) | called by muse, mutect2, varscan2
- PPCS | c.438A>G p.A146= | Silent (SNP) | VAF 264/306 reads (86%) | called by muse, mutect2, varscan2
- PPP2R5C | c.48C>G p.A16= | Silent (SNP) | VAF 81/470 reads (17%) | called by muse, mutect2, varscan2
- PSG1 | c.108C>T p.V36= | Silent (SNP) | VAF 109/495 reads (22%) | called by muse, mutect2, varscan2
- PTMA | c.30C>G p.S10= | Silent (SNP) | VAF 249/474 reads (53%) | called by muse, mutect2, varscan2
- PTPN3 | c.1542A>C p.T514= | Silent (SNP) | VAF 144/175 reads (82%) | called by muse, mutect2, varscan2
- QSER1 | c.3336G>T p.P1112= (on ENST00000399302; = p.P1241= on NM_001076786.3) | Silent (SNP) | VAF 162/353 reads (46%) | catalogued as COSV67901218; called by muse, mutect2, varscan2
- RGPD1 | c.4029T>C p.S1343= (on ENST00000409776; = p.S1351= on NM_001024457.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 238/548 reads (43%) | called by muse, mutect2, varscan2
- RNF114 | c.297C>T p.F99= | Silent (SNP) | VAF 120/268 reads (45%) | called by muse, mutect2, varscan2
- RPS27A | c.366T>A p.P122= | Silent (SNP) | VAF 217/501 reads (43%) | called by muse, mutect2, varscan2
- RYR2 | c.14169C>A p.A4723= | Silent (SNP) | VAF 52/276 reads (19%) | called by muse, mutect2, varscan2
- SELP | c.1551G>A p.Q517= | Silent (SNP) | VAF 182/536 reads (34%) | called by muse, mutect2, varscan2
- SETD1A | c.4095G>T p.G1365= | Silent (SNP) | VAF 368/712 reads (52%) | catalogued as rs990642598; called by muse, varscan2
- SLAMF7 | c.294T>C p.N98= | Silent (SNP) | VAF 287/608 reads (47%) | called by muse, mutect2, varscan2
- SPATA5 | c.591G>C p.G197= | Silent (SNP) | VAF 114/485 reads (24%) | called by muse, mutect2, varscan2
- SRBD1 | c.1053C>T p.Y351= | Silent (SNP) | VAF 179/371 reads (48%) | called by muse, mutect2, varscan2
- SYNE3 | c.567G>A p.V189= | Silent (SNP) | VAF 215/604 reads (36%) | catalogued as COSV100515827; called by muse, mutect2, varscan2
- TBX3 | c.1818G>C p.T606= (on ENST00000257566 / NM_016569.4; = p.T586= on NM_005996.4) | Silent (SNP) | VAF 312/395 reads (79%) | catalogued as COSV57473897; called by muse, mutect2, varscan2
- TDRD6 | c.4491A>G p.S1497= | Silent (SNP) | VAF 121/212 reads (57%) | called by muse, mutect2, varscan2
- TENT2 | c.1116T>A p.A372= | Silent (SNP) | VAF 175/307 reads (57%) | catalogued as rs1412224504; called by muse, mutect2, varscan2
- TENT4A | c.1359C>T p.I453= | Silent (SNP) | VAF 80/497 reads (16%) | catalogued as rs1382692031; called by muse, mutect2, varscan2
- TIGD4 | c.117A>G p.K39= | Silent (SNP) | VAF 80/476 reads (17%) | called by muse, mutect2, varscan2
- TLCD3A | c.465G>A p.L155= | Silent (SNP) | VAF 148/186 reads (80%) | called by muse, varscan2
- TMEM132C | c.192C>A p.L64= | Silent (SNP) | VAF 234/289 reads (81%) | catalogued as rs1358063274; called by muse, mutect2, varscan2
- TMEM132D | c.1368C>G p.S456= | Silent (SNP) | VAF 272/314 reads (87%) | called by muse, mutect2, varscan2
- TMEM203 | c.234G>T p.R78= | Silent (SNP) | VAF 304/368 reads (83%) | called by muse, mutect2, varscan2
- TMEM275 | c.294G>T p.A98= | Silent (SNP) | VAF 220/260 reads (85%) | called by muse, varscan2
- TNN | c.3373C>A p.R1125= | Silent (SNP) | VAF 130/409 reads (32%) | called by muse, mutect2, varscan2
- TNRC18 | c.4317C>T p.D1439= | Silent (SNP) | VAF 311/396 reads (79%) | catalogued as rs773309038; called by muse, mutect2, varscan2
- TRAF7 | c.1083A>G p.L361= | Silent (SNP) | VAF 150/274 reads (55%) | called by muse, mutect2, varscan2
- TRBV2 | c.120G>A p.L40= | Silent (SNP) | VAF 155/310 reads (50%) | called by muse, mutect2, varscan2
- TRGV9 | c.141A>G p.G47= | Silent (SNP) | VAF 83/302 reads (27%) | called by muse, mutect2, varscan2
- TSPYL2 | c.165A>G p.A55= | Silent (SNP) | VAF 432/472 reads (92%) | called by muse, varscan2
- TST | c.405G>A p.L135= | Silent (SNP) | VAF 155/493 reads (31%) | called by muse, mutect2, varscan2
- UNC45B | c.2586G>C p.L862= | Silent (SNP) | VAF 182/214 reads (85%) | catalogued as rs778559923, COSV52096432; called by muse, mutect2, varscan2
- VIPAS39 | c.975A>G p.K325= | Silent (SNP) | VAF 317/603 reads (53%) | called by muse, mutect2, varscan2
- ZFAT | c.867C>T p.H289= | Silent (SNP) | VAF 132/455 reads (29%) | catalogued as rs1418002105; called by muse, mutect2, varscan2
- ZMYND15 | c.786A>G p.R262= | Silent (SNP) | VAF 242/304 reads (80%) | called by muse, mutect2, varscan2
- ZNF382 | c.1245G>A p.K415= | Silent (SNP) | VAF 163/533 reads (31%) | called by muse, mutect2, varscan2
- ZNF568 | c.402G>A p.A134= | Silent (SNP) | VAF 226/445 reads (51%) | catalogued as rs932866401; called by muse, mutect2, varscan2
- ZNF614 | c.900C>T p.R300= | Silent (SNP) | VAF 96/435 reads (22%) | called by muse, mutect2, varscan2
- ZNF710 | c.39C>G p.A13= | Silent (SNP) | VAF 80/349 reads (23%) | called by muse, mutect2, varscan2
- ZNF804B | c.489G>A p.K163= | Silent (SNP) | VAF 88/332 reads (27%) | catalogued as rs1327759702; called by muse, mutect2, varscan2
- ZNF845 | c.1413T>C p.D471= | Silent (SNP) | VAF 91/360 reads (25%) | catalogued as COSV72004110; called by muse, mutect2, varscan2
- ZNF879 | c.711T>C p.C237= | Silent (SNP) | VAF 184/335 reads (55%) | catalogued as rs754545501; called by muse, mutect2, varscan2
- AC010655.3 | n.59_60del | RNA (DEL) | VAF 64/320 reads (20%) | called by mutect2, pindel, varscan2
- AC063924.1 | chr12:45439838 C>G | 5'Flank (SNP) | VAF 130/319 reads (41%) | called by muse, mutect2, varscan2
- ARIH2 | chr3:48918483 T>C | 5'Flank (SNP) | VAF 144/353 reads (41%) | called by muse, mutect2, varscan2
- CSMD3 | c.178+59915C>T | Intron (SNP) | VAF 101/295 reads (34%) | called by muse, mutect2, varscan2
- EPHA8 | c.1315+79C>T | Intron (SNP) | VAF 156/369 reads (42%) | catalogued as COSV99384383; called by muse, mutect2, varscan2
- FAM217A | c.-74C>A | 5'UTR (SNP) | VAF 350/591 reads (59%) | called by muse, mutect2, varscan2
- FHL2 | c.-124G>T | 5'UTR (SNP) | VAF 493/1048 reads (47%) | catalogued as rs914887435; called by muse, mutect2, varscan2
- FLVCR2 | c.670-16500A>C | Intron (SNP) | VAF 94/487 reads (19%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+19975del | Intron (DEL) | VAF 201/329 reads (61%) | called by mutect2, pindel, varscan2
- LBX2 | chr2:74502677 G>A | 5'Flank (SNP) | VAF 215/540 reads (40%) | catalogued as COSV52043618; called by muse, mutect2, varscan2
- MBNL1 | c.1016-699A>G | Intron (SNP) | VAF 223/788 reads (28%) | catalogued as rs778821940; called by muse, mutect2, varscan2
- PAX4 | c.145-64C>A | Intron (SNP) | VAF 234/445 reads (53%) | called by muse, mutect2, varscan2
- PDE4D | c.455+124678C>G | Intron (SNP) | VAF 65/187 reads (35%) | called by muse, mutect2, varscan2
- RNASE4 | c.-1G>T | 5'UTR (SNP) | VAF 107/342 reads (31%) | called by muse, mutect2, varscan2
- RPGR | c.2520+481G>T | Intron (SNP) | VAF 235/263 reads (89%) | called by muse, mutect2, varscan2
- SORBS2 | c.-197-6006G>T | Intron (SNP) | VAF 88/522 reads (17%) | called by muse, mutect2, varscan2
- SPATA3 | c.-1C>G | 5'UTR (SNP) | VAF 134/336 reads (40%) | called by muse, mutect2, varscan2
- SUCO | chr1:172532483 T>G | 5'Flank (SNP) | VAF 76/388 reads (20%) | catalogued as COSV55270322, COSV99742904, COSV99744253; called by muse, mutect2, varscan2
- SUMF2 | c.733+262G>T | Intron (SNP) | VAF 131/463 reads (28%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3528G>C | Intron (SNP) | VAF 181/665 reads (27%) | called by muse, mutect2, varscan2
- ZSCAN32 | chr16:3382865 C>G | 3'Flank (SNP) | VAF 78/265 reads (29%) | called by muse, mutect2, varscan2
